TARGET case TARGET-20-PAYGWX-Unsorted — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/97178dd6-8b5c-433a-9fda-bc1029649d6f

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 0.6 years (235 days); Year of diagnosis: 2017; Days to last follow up: 9 days; Sites of involvement: Central nervous system.
   Treatment given: Protocol identifier: AAML1031.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.

Follow-up (1 entry)
- Days to follow up: 9 days; Event-free: no event (relapse, second malignancy or death) recorded through day 9; Year of follow up: 2017.

Molecular and laboratory tests (laboratory values grouped by visit day)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Negative.
- NPM1 mutation, nos: Negative.
- Day 0: Leukocytes 15.3 ×10³/µL; Blast Count 0%; Bone Marrow blast count 95%.

Biospecimens (1 sample)
- Sample TARGET-20-PAYGWX-Unsorted-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AAML1031_AAML0631_additionalCasesForSortedCellsAndCBExperiment_20230720.xlsx:
- First Event: Censored
- Event Free Survival Time in Days: 9
- Overall Survival Time in Days: 9
- WBC at Diagnosis: 15.3
- Bone marrow leukemic blast percentage (%): 95
- Peripheral blasts (%): 0
- CNS disease: Yes
- Chloroma: No
- FLT3/ITD positive?: No
- NPM mutation: No
- CEBPA mutation: No
- CR status at end of course 1: unevaluable
- CR status at end of course 2: unevaluable
